Somatic mutation profile of tumor specimen TCGA-OR-A5L4-01A (aliquot TCGA-OR-A5L4-01A-11D-A29I-10) from TCGA case TCGA-OR-A5L4, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 48.8 years (17,819 days).
Specimen TCGA-OR-A5L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34b419d2-1855-4eca-875f-43b20d03f92e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L4-10A (Blood Derived Normal), aliquot TCGA-OR-A5L4-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/561d12dc-7a20-4408-8a56-f778d09ba737

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECT2L | c.1477C>A p.Q493K | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV62884571; called by muse, mutect2, varscan2
- IGSF6 | c.680_682del p.N227del | In Frame Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs562061536; called by pindel, varscan2
- LNX1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1352651156; called by muse, varscan2
- NLRP3 | c.2638C>G p.P880A | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV60224661; called by muse, mutect2, varscan2
- TAS2R31 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1360908528; called by muse, mutect2, varscan2
- BEND3 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.411); called by muse, mutect2
- CDHR2 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.194); called by muse, varscan2
- CUX1 | c.658G>A p.E220K (on ENST00000292535 / NM_181552.4; = p.E231K on NM_001913.5) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DAAM1 | c.3179T>C p.I1060T | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- EEA1 | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GMEB1 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 122/162 reads (75%) | SIFT tolerated (0.6); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- INPP5B | c.421T>A p.F141I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LAMA1 | c.4135G>A p.G1379R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LNX1 | c.259T>A p.C87S | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MALL | c.105+1G>A p.X35_splice | Splice Site (SNP) | VAF 98/122 reads (80%) | called by muse, varscan2
- MIER3 | c.909del p.I304Yfs*6 (on ENST00000381199 / NM_001297599.2; = p.I303Yfs*6 on NM_152622.4) | Frame Shift Del (DEL) | VAF 36/169 reads (21%) | called by mutect2, pindel, varscan2
- SNTA1 | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ABLIM1 | c.1353G>A p.T451= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as rs758416758; called by muse, mutect2, varscan2
- ATP10B | c.3381C>T p.L1127= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as rs370433512; called by muse, mutect2, varscan2
- FNBP4 | c.849G>T p.T283= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as rs777215176, COSV55447664; called by muse, mutect2, varscan2
- MRI1 | c.831C>T p.Y277= (on ENST00000040663 / NM_001031727.4; = p.Y230= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs775756673, COSV50005377; called by muse, mutect2, varscan2
- PCDHA3 | c.1842G>T p.G614= | Silent (SNP) | VAF 76/343 reads (22%) | called by muse, mutect2, varscan2
- PGAP6 | c.1200C>T p.L400= | Silent (SNP) | VAF 58/215 reads (27%) | called by muse, mutect2, varscan2
- ZNF264 | c.1422C>T p.F474= | Silent (SNP) | VAF 68/142 reads (48%) | called by muse, varscan2
